Somatic mutation profile of tumor specimen TCGA-58-A46M-01A (aliquot TCGA-58-A46M-01A-11D-A24D-08) from TCGA case TCGA-58-A46M, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.9 years (22,592 days).
Specimen TCGA-58-A46M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 444a2ba4-0786-4e6b-8f2d-5278ccc78856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-A46M-10A (Blood Derived Normal), aliquot TCGA-58-A46M-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fe66488-b4a0-4782-9e58-4861f56087c5

The open-access MAF lists 453 somatic variants for this specimen: 326 protein-altering or splice-affecting, 119 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 119, Nonsense Mutation 24, Frame Shift Del 11, Splice Site 9, RNA 4, Intron 2, Splice Region 2, Frame Shift Ins 2, In Frame Del 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 33/48 reads (69%) | hotspot (GDC flag); catalogued as rs1206165503, CM107391, COSV52661900, COSV52703354, COSV52753201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.359T>A p.L120H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429512; called by muse, mutect2, varscan2
- ABHD17B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV100330219; called by muse, mutect2
- ACAD10 | c.1062-1G>T p.X354_splice | Splice Site (SNP) | VAF 33/148 reads (22%) | catalogued as COSV100564229; called by muse, varscan2
- ACIN1 | c.3484G>T p.E1162* | Nonsense Mutation (SNP) | VAF 69/156 reads (44%) | catalogued as COSV99399698; called by muse, mutect2, varscan2
- ADAM2 | c.1161T>A p.C387* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99697374; called by muse, mutect2, varscan2
- ADAMTS16 | c.1927del p.D643Tfs*31 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as COSV56997836; called by mutect2, pindel, varscan2
- ADAMTS16 | c.3332C>A p.P1111Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV56995955, COSV99941372; called by muse, mutect2, varscan2
- ADAMTS20 | c.1179A>T p.K393N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101239380; called by muse, mutect2, varscan2
- ADORA2A | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.311); catalogued as COSV100418044; called by muse, mutect2, varscan2
- AFF3 | c.3127A>T p.M1043L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100419021; called by muse, mutect2, varscan2
- AL592490.1 | c.2150G>T p.G717V | Missense Mutation (SNP) | VAF 108/158 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101308207; called by muse, mutect2, varscan2
- ANKFN1 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100593546; called by muse, mutect2, varscan2
- ANKRD34B | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as COSV100103535; called by muse, mutect2, varscan2
- APBA2 | c.945C>A p.H315Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376263872, COSV101382255, COSV68794281; called by mutect2, varscan2
- APMAP | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468629; called by muse, mutect2, varscan2
- ASAP2 | c.1987C>A p.R663S | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99856261; called by muse, mutect2, varscan2
- ASTN2 | c.3534C>G p.H1178Q (on ENST00000313400 / NM_001365069.1; = p.H1127Q on NM_014010.5) | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.302); catalogued as COSV99940881; called by muse, mutect2, varscan2
- ASXL2 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372578149; called by muse, mutect2, varscan2
- ATOH8 | c.77T>A p.L26H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100092680; called by muse, mutect2, varscan2
- ATXN1 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99786554; called by muse, mutect2, varscan2
- ATXN1 | c.1507G>T p.G503W | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99786555; called by muse, mutect2, varscan2
- BABAM1 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.009); catalogued as rs757440172, COSV99394275; called by muse, varscan2
- BAIAP2L1 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.727); catalogued as COSV50055251, COSV99134200; called by muse, mutect2, varscan2
- BBS7 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99144952; called by muse, mutect2, varscan2
- BICC1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1046249158, COSV54067305; called by muse, mutect2, varscan2
- CA8 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100526952; called by muse, mutect2, varscan2
- CACNA2D2 | c.2173T>C p.F725L (on ENST00000479441 / NM_001174051.3; = p.F718L on NM_006030.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99817754; called by muse, mutect2, varscan2
- CACNB2 | c.380C>T p.A127V (on ENST00000324631 / NM_201596.3; = p.A72V on NM_000724.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs200367454, CM109292, COSV56614882; ClinVar: likely benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CADM2 | c.1042G>T p.A348S (on ENST00000407528 / NM_001167674.2; = p.A350S on NM_153184.4) | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101056061; called by muse, mutect2, varscan2
- CAPN2 | c.1690+1G>T p.X564_splice | Splice Site (SNP) | VAF 76/118 reads (64%) | catalogued as rs748554233, COSV99688951; called by muse, mutect2, varscan2
- CARNMT1 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1367443973, COSV100961741; called by muse, mutect2, varscan2
- CAVIN1 | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.191); catalogued as COSV100824551; called by muse, mutect2, varscan2
- CDC42BPG | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61345772; called by muse, mutect2, varscan2
- CDH10 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100051622, COSV52575233, COSV52579534; called by muse, mutect2, varscan2
- CDH10 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV100051624; called by muse, mutect2, varscan2
- CDH6 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 85/118 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99419317; called by muse, mutect2, varscan2
- CDK13 | c.4432G>A p.G1478R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99475598; called by muse, mutect2, varscan2
- CDR1 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 100/156 reads (64%) | catalogued as COSV100983417; called by muse, mutect2, varscan2
- CFAP47 | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV99935112; called by muse, mutect2, varscan2
- CHMP2B | c.324A>T p.T108= | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99773447; called by muse, mutect2, varscan2
- CHORDC1 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100272058; called by muse, mutect2, varscan2
- CHRNA6 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 120/232 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99373248; called by muse, mutect2, varscan2
- CLEC3A | c.79G>T p.D27Y (on ENST00000651443; = p.D18Y on NM_005752.6) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100222238; called by muse, mutect2, varscan2
- CNTN1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636194; called by muse, mutect2, varscan2
- CNTNAP5 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.224); catalogued as COSV101443612; called by muse, mutect2, varscan2
- COL11A1 | c.2186A>T p.D729V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100616732; called by muse, mutect2
- COL1A2 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.081); catalogued as COSV99799855; called by muse, mutect2, varscan2
- COL22A1 | c.2611G>T p.G871* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57322681; called by muse, mutect2, varscan2
- COL5A1 | c.1390-2A>C p.X464_splice | Splice Site (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100880017; called by muse, mutect2, varscan2
- COL5A2 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880380; called by muse, mutect2, varscan2
- COPG1 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as COSV100135627, COSV59112995, COSV59113805; called by muse, mutect2, varscan2
- CORIN | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99903103; called by muse, mutect2, varscan2
- CORIN | c.496A>G p.M166V | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99903700; called by muse, mutect2, varscan2
- CREB3L2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV100381958; called by muse, mutect2, varscan2
- CREB3L2 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100381963; called by muse, mutect2, varscan2
- CSF2RA | c.198_200del p.K66del | In Frame Del (DEL) | VAF 49/106 reads (46%) | catalogued as rs1329973338; called by pindel, varscan2
- CSF2RA | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1181481612, COSV100817746; called by muse, mutect2, varscan2
- CSMD2 | c.4568G>T p.R1523L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753808964, COSV53925291, COSV99590762; called by muse, mutect2, varscan2
- CSMD3 | c.10390C>T p.P3464S (on ENST00000297405 / NM_001363185.1; = p.P3295S on NM_052900.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141126792, COSV52122184; called by muse, mutect2, varscan2
- CSMD3 | c.7634T>C p.V2545A (on ENST00000297405 / NM_001363185.1; = p.V2441A on NM_052900.3) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.369); catalogued as COSV99835519; called by muse, mutect2, varscan2
- CSPP1 | c.3373C>T p.P1125S (on ENST00000676605; = p.P1084S on NM_024790.6) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.195); catalogued as rs771553662, COSV99138608; called by muse, mutect2, varscan2
- CST3 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV100976865; called by muse, mutect2, varscan2
- CYCS | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as COSV99995050; called by muse, mutect2, varscan2
- CYP2B6 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.617); catalogued as COSV100137579; called by muse, mutect2, varscan2
- DAPK1 | c.4003G>T p.G1335C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63792849; called by muse, mutect2, varscan2
- DCDC1 | c.3388G>A p.D1130N (on ENST00000597505 / NM_001367979.1; = p.D237N on NM_020869.3) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.159); catalogued as rs746432043, COSV100338319, COSV60315721; called by muse, mutect2, varscan2
- DDX10 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV100489581; called by muse, mutect2, varscan2
- DGKI | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs1441076823, COSV99934831; called by muse, mutect2, varscan2
- DIPK2B | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101211675; called by muse, mutect2, varscan2
- DLC1 | c.2031G>C p.K677N (on ENST00000276297 / NM_001348081.2; = p.K240N on NM_006094.5) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV99363324; called by muse, mutect2, varscan2
- DNAJC22 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as COSV101222541; called by muse, mutect2, varscan2
- DNAJC5 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs933246467, COSV100694235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK2 | c.778A>T p.I260F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99374748; called by muse, mutect2, varscan2
- DPPA2 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV101524766; called by muse, mutect2, varscan2
- DST | c.10945C>T p.L3649F (on ENST00000361203 / NM_001374722.1; = p.L1237F on NM_015548.5) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV99756486; called by muse, mutect2, varscan2
- DYSF | c.2975G>T p.W992L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM090603, COSV99247438; called by muse, mutect2, varscan2
- DZIP3 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100847805; called by muse, mutect2, varscan2
- EDF1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56376722; called by muse, mutect2, varscan2
- ENOPH1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV99908687; called by muse, mutect2, varscan2
- EPB42 | c.1597C>A p.L533I (on ENST00000441366 / NM_001114134.2; = p.L563I on NM_000119.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV100281988; called by muse, mutect2
- EPC1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99552959; called by muse, mutect2, varscan2
- EPHA1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs201188496; called by muse, mutect2, varscan2
- EPHA5 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99899142; called by muse, mutect2, varscan2
- EPHB1 | c.2054G>A p.G685D | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213208, COSV67675425; called by muse, mutect2, varscan2
- F5 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100889096, COSV100889121; called by muse, mutect2, varscan2
- FAAP100 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100585387; called by muse, mutect2, varscan2
- FAM135B | c.1753T>A p.Y585N | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99424277; called by muse, mutect2, varscan2
- FAM149A | c.931G>T p.E311* (on ENST00000356371 / NM_001367768.2; = p.E20* on NM_015398.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99906561; called by muse, mutect2, varscan2
- FAM47C | c.2824T>A p.Y942N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100792613; called by muse, mutect2, varscan2
- FBXO15 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs549233857, COSV54042674; called by muse, mutect2, varscan2
- FBXW11 | c.374-1G>T p.X125_splice | Splice Site (SNP) | VAF 66/183 reads (36%) | catalogued as COSV99440634; called by muse, mutect2, varscan2
- FKRP | c.1343C>A p.P448Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM013812, COSV100586694; called by muse, varscan2
- FLG | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 79/556 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1220069584, COSV64245113; called by muse, mutect2, varscan2
- FLG | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); catalogued as COSV100911614, COSV64240714; called by muse, mutect2, varscan2
- FLI1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99857797; called by muse, mutect2, varscan2
- FMO5 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99567115; called by muse, mutect2, varscan2
- FN3KRP | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as rs976511691, COSV99485013; called by muse, mutect2
- FPR1 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100494111; called by muse, mutect2, varscan2
- FRMPD4 | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV101042984; called by muse, mutect2, varscan2
- FRY | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs746124126, COSV100969324; called by muse, varscan2
- FRY | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100969326; called by muse, varscan2
- FSTL5 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as rs141917472, COSV60192986; called by muse, mutect2, varscan2
- GABRB3 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV100160132, COSV54658447; called by muse, mutect2, varscan2
- GADD45G | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99378609; called by muse, mutect2, varscan2
- GALNT13 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67214636; called by muse, mutect2, varscan2
- GFRAL | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs867799076, COSV100475229; called by muse, mutect2, varscan2
- GLI1 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1182931922, COSV99954188; called by muse, mutect2, varscan2
- GLP2R | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99302051; called by muse, mutect2
- GNAQ | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99681132; called by muse, mutect2, varscan2
- GOLGA3 | c.2675G>T p.G892V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV99206177; called by muse, mutect2, varscan2
- GORASP2 | c.961_966dup p.N321_L322dup | In Frame Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs776779471; called by mutect2, varscan2
- GP6 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100117420, COSV59979788; called by muse, mutect2, varscan2
- GPATCH1 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566031651, COSV99404060; called by muse, mutect2, varscan2
- GPM6B | c.359A>C p.H120P | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as COSV100366229; called by muse, mutect2, varscan2
- GTF3C1 | c.2261G>A p.S754N | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100649442; called by muse, mutect2, varscan2
- H4-16 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV63761826; called by muse, mutect2, varscan2
- HAL | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701450, COSV99701628; called by muse, mutect2, varscan2
- HAPLN3 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as COSV100613756; called by muse, mutect2
- HLX | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1383883307, COSV100854542, COSV65045175; called by muse, mutect2, varscan2
- HOOK2 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as COSV99317598; called by muse, varscan2
- IFT43 | c.23A>T p.D8V | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99466164; called by muse, mutect2, varscan2
- IFT52 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV100887611; called by muse, mutect2, varscan2
- IFT80 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100424770; called by muse, mutect2
- IGF2R | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100807442; called by muse, mutect2, varscan2
- IGHV3-15 | c.208A>T p.I70F | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs782403577; called by muse, mutect2, varscan2
- IL17A | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100391539, COSV60684255; called by muse, mutect2, varscan2
- INSC | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.163); catalogued as rs774420513, COSV101089216; called by muse, mutect2, varscan2
- ITGA8 | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.772); catalogued as COSV100959239; called by muse, mutect2, varscan2
- ITGBL1 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV101095417; called by muse, mutect2, varscan2
- JAK2 | c.2320G>C p.A774P | Missense Mutation (SNP) | VAF 96/128 reads (75%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV101073771; called by muse, mutect2, varscan2
- KLHDC7B | c.1519G>A p.A507T (on ENST00000395676; = p.A1148T on NM_138433.5) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs149211452; called by muse, mutect2, varscan2
- KLHL4 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as COSV100909636; called by muse, varscan2
- KMT2C | c.7163G>T p.R2388L | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100072263, COSV51483454; called by muse, mutect2, varscan2
- KMT5B | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs142141344, COSV58567085, COSV58567993; called by muse, mutect2, varscan2
- KRT14 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51420356, COSV99391037; called by muse, mutect2, varscan2
- KRT73 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988547; called by muse, mutect2, varscan2
- LCE1D | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 43/153 reads (28%) | PolyPhen benign (0.089); catalogued as rs776581978, COSV100405901; called by muse, mutect2, varscan2
- LCP1 | c.1070G>C p.R357P | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV100549909, COSV100549989; called by muse, mutect2, varscan2
- LILRB5 | c.1735C>A p.P579T (on ENST00000449561 / NM_001081442.3; = p.P578T on NM_006840.5) | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs200586611, COSV60260258; called by muse, mutect2, varscan2
- LSG1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV99503253; called by muse, mutect2, varscan2
- MAGEL2 | c.2688G>T p.E896D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100045958; called by muse, mutect2, varscan2
- MAML2 | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV101594125; called by muse, mutect2, varscan2
- MAP2K3 | c.680G>T p.C227F (on ENST00000342679 / NM_145109.3; = p.C198F on NM_002756.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100383940; called by muse, mutect2
- MAP3K9 | c.1246A>G p.K416E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV101173636; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1412475968, COSV99571479; called by muse, mutect2, varscan2
- MAS1L | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV101009688; called by muse, mutect2, varscan2
- MC5R | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100229048; called by muse, mutect2, varscan2
- MCM10 | c.967C>T p.L323F (on ENST00000484800 / NM_182751.3; = p.L322F on NM_018518.5) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101098039; called by muse, varscan2
- MCOLN3 | c.1297G>T p.V433L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100352769, COSV62013791; called by muse, mutect2, varscan2
- MED12L | c.491G>C p.C164S | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.966); catalogued as COSV99853298; called by muse, mutect2, varscan2
- MED23 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV100645028; called by muse, mutect2, varscan2
- MFF | c.970A>T p.M324L | Missense Mutation (SNP) | VAF 73/103 reads (71%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100449331, COSV58826211; called by muse, mutect2, varscan2
- MKX | c.423G>C p.L141F | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV101008776; called by muse, mutect2, varscan2
- MMP16 | c.1814A>T p.E605V | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99688479; called by muse, mutect2, varscan2
- MMP16 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV54179992; called by muse, mutect2, varscan2
- MOCS3 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724282; called by muse, mutect2, varscan2
- MTCL1 | c.2665T>C p.F889L (on ENST00000306329 / NM_001378206.1; = p.F529L on NM_015210.4) | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1235559410, COSV100094642; called by muse, mutect2, varscan2
- MUC16 | c.5729C>T p.P1910L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67483815; called by muse, mutect2, varscan2
- MUC4 | c.15157T>A p.S5053T (on ENST00000463781 / NM_018406.7; = p.S817T on NM_004532.6) | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100204851; called by muse, mutect2, varscan2
- MYCT1 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65891766; called by muse, mutect2, varscan2
- MYCT1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV65892163; called by muse, mutect2, varscan2
- MYH1 | c.4107C>A p.N1369K | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99876040; called by muse, mutect2, varscan2
- MYH7 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs878853840, CM122332, COSV100806152, COSV100806164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.5037C>A p.S1679R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV101261587; called by muse, mutect2, varscan2
- MYT1L | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV67732181; called by muse, varscan2
- MYT1L | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101220821, COSV67719126; called by muse, varscan2
- NAV3 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.828); catalogued as rs745934944, COSV99891334; called by muse, mutect2, varscan2
- NCAPH2 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.898); catalogued as COSV99410591; called by muse, mutect2
- NCOR2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.155); catalogued as rs757710006, COSV100657362, COSV100657371; called by muse, mutect2, varscan2
- NELL1 | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.027); catalogued as COSV100121689; called by muse, mutect2, varscan2
- NLGN1 | c.1796G>T p.R599I | Missense Mutation (SNP) | VAF 164/312 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100849412; called by muse, mutect2, varscan2
- NLRP13 | c.976T>A p.L326M | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV100738276; called by muse, mutect2, varscan2
- NLRP9 | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100243099; called by muse, mutect2, varscan2
- NOX4 | c.1218-2A>T p.X406_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99629405, COSV99630681; called by muse, mutect2, varscan2
- NR2C2AP | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100284533; called by muse, mutect2, varscan2
- NUDT10 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs143500991, COSV100726822, COSV62854227; called by muse, mutect2
- NUP107 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99971767; called by muse, mutect2, varscan2
- OR10A2 | c.238T>A p.S80T | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as COSV100225046; called by muse, mutect2, varscan2
- OR10Q1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.415); catalogued as COSV100372288; called by muse, mutect2, varscan2
- OR14C36 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV100507551, COSV58601961; called by muse, mutect2
- OR1J1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV99403165; called by muse, mutect2, varscan2
- OR2C3 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 50/71 reads (70%) | catalogued as COSV100825707; called by muse, mutect2
- OR4K5 | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 130/662 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755932618, COSV100262400, COSV60002787, COSV60004118; called by muse, mutect2, varscan2
- OR4M1 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 115/592 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773544136, COSV100271239; called by muse, mutect2, varscan2
- OR51L1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100386437; called by muse, mutect2, varscan2
- OR52A5 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263464; called by muse, mutect2, varscan2
- OR52B2 | c.826A>G p.I276V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1429633026, COSV101603948; called by muse, mutect2, varscan2
- OR52N2 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100396130, COSV57676484; called by muse, mutect2, varscan2
- OR52N4 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100421683, COSV57891201, COSV57891238; called by muse, mutect2, varscan2
- OR5B2 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV100222890; called by muse, mutect2, varscan2
- OR5T1 | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV100479031; called by muse, mutect2, varscan2
- PAPSS1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99492068; called by muse, mutect2, varscan2
- PAXIP1 | c.3176A>C p.Q1059P | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101249744; called by muse, mutect2, varscan2
- PCDHA13 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56516192; called by muse, mutect2, varscan2
- PCDHB9 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53375191, COSV53379472; called by muse, mutect2, varscan2
- PCDHGA5 | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53933542, COSV99539014; called by muse, mutect2, varscan2
- PCDHGA5 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as COSV99539015; called by muse, mutect2, varscan2
- PCNX2 | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 86/122 reads (70%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.015); catalogued as COSV99267862; called by muse, mutect2, varscan2
- PDGFRB | c.1808-1G>T p.X603_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99940649; called by muse, mutect2, varscan2
- PGM5 | c.1552A>T p.T518S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101123930; called by muse, mutect2, varscan2
- PGR | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54804760, COSV99678432; called by muse, mutect2, varscan2
- PIGV | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs779441883, COSV99314941; called by muse, mutect2, varscan2
- PIK3AP1 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV100225802; called by muse, mutect2, varscan2
- PLCH1 | c.4072A>T p.S1358C (on ENST00000340059 / NM_001130960.2; = p.S1350C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV100396975; called by muse, mutect2, varscan2
- PLCH2 | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99616423; called by muse, mutect2, varscan2
- PLCL1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV101406997; called by muse, mutect2, varscan2
- PNLIPRP3 | c.468A>T p.E156D | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100982491; called by muse, mutect2, varscan2
- POTEH | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV100624981; called by muse, mutect2, varscan2
- PRDM9 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV57003325, COSV99031446; called by muse, mutect2, varscan2
- PRKAA2 | c.1582G>T p.V528F | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100982873; called by muse, mutect2, varscan2
- PSKH2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as rs928366643, COSV52608988, COSV52612913; called by muse, mutect2, varscan2
- PTPN23 | c.1160T>G p.I387S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99650615; called by muse, mutect2
- PXDN | c.2354G>T p.R785L | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as COSV99413651; called by muse, mutect2, varscan2
- PYGM | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM071070, COSV99377165; called by muse, mutect2, varscan2
- PYGO2 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.346); catalogued as COSV100868940; called by muse, mutect2
- RABGEF1 | c.217C>T p.R73* (on ENST00000439720 / NM_001287061.2; = p.R60* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs772771696, COSV99534845; called by muse, mutect2, varscan2
- RABL3 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99846516; called by muse, mutect2, varscan2
- RALGDS | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV100924455; called by muse, mutect2, varscan2
- RASGRF1 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV101369646; called by muse, mutect2, varscan2
- RBBP6 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 144/221 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV100154621; called by muse, mutect2, varscan2
- REEP1 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.354); catalogued as COSV99382905; called by muse, mutect2, varscan2
- RFFL | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99265347; called by muse, mutect2, varscan2
- RGS3 | c.1951C>T p.Q651* (on ENST00000350696 / NM_001282923.2; = p.Q539* on NM_017790.4) | Nonsense Mutation (SNP) | VAF 76/126 reads (60%) | catalogued as COSV100465344; called by muse, mutect2, varscan2
- RIMS1 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99327232; called by muse, mutect2, varscan2
- RPAIN | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as COSV100506852; called by muse, mutect2, varscan2
- RRP8 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs200483016, COSV99601922; called by muse, mutect2, varscan2
- SALL2 | c.2867A>G p.K956R | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100444390; called by muse, mutect2, varscan2
- SBK2 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV100705139, COSV60014020; called by muse, mutect2, varscan2
- SERTAD3 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100475077, COSV100475113; called by muse, mutect2, varscan2
- SEZ6L | c.2129C>T p.T710M | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.231); catalogued as rs762003952, COSV50698695; called by muse, mutect2, varscan2
- SFSWAP | c.2279A>T p.K760M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55522495, COSV55526452, COSV99906123; called by muse, mutect2, varscan2
- SGK2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV100414672; called by muse, mutect2, varscan2
- SHCBP1L | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100841078, COSV62357153; called by muse, mutect2, varscan2
- SHROOM3 | c.818C>A p.P273Q | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99934442; called by muse, mutect2
- SI | c.2287T>A p.Y763N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015677; called by muse, mutect2, varscan2
- SI | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV100015678; called by muse, varscan2
- SIN3A | c.2415G>C p.Q805H | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100845159; called by muse, mutect2, varscan2
- SKAP2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100591942; called by muse, mutect2, varscan2
- SLC25A4 | c.556A>C p.I186L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99861257; called by muse, mutect2, varscan2
- SLCO6A1 | c.1055A>G p.Q352R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV101134463; called by muse, mutect2, varscan2
- SLITRK4 | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 28/44 reads (64%) | catalogued as COSV100567234, COSV100567367; called by muse, mutect2, varscan2
- SNTG2 | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100422851; called by muse, mutect2
- SOX14 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV100048215; called by muse, mutect2, varscan2
- SPACA1 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV99389544; called by muse, mutect2, varscan2
- SPTA1 | c.6943C>T p.H2315Y | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100935031; called by muse, mutect2, varscan2
- SPTA1 | c.5416G>A p.E1806K | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as COSV100935033, COSV63759387; called by muse, mutect2, varscan2
- SPTBN2 | c.3856G>A p.D1286N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.054); catalogued as COSV100019472; called by muse, mutect2, varscan2
- SPTY2D1 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100311698; called by muse, mutect2, varscan2
- SRF | c.513G>A p.K171= | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99541854; called by muse, mutect2, varscan2
- SRRM4 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs1428404875, COSV99938599; called by muse, mutect2, varscan2
- SUCO | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55267380; called by muse, mutect2
- SYCP2L | c.1180T>A p.S394T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99305243; called by muse, mutect2, varscan2
- SYNCRIP | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100784226; called by muse, mutect2, varscan2
- SYTL2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs768108453, COSV60355855; called by muse, mutect2, varscan2
- TAAR6 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV51583437; called by muse, mutect2, varscan2
- TAS2R40 | c.112T>C p.F38L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV101283000; called by muse, mutect2, varscan2
- TBC1D1 | c.258T>A p.D86E | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV99791342; called by muse, mutect2, varscan2
- TBX15 | c.1489G>A p.G497R (on ENST00000369429 / NM_001330677.2; = p.G391R on NM_152380.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.365); catalogued as rs940885857, COSV52868381; called by muse, mutect2, varscan2
- TBX3 | c.287A>T p.E96V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99983803; called by muse, mutect2, varscan2
- TENM4 | c.5269C>T p.R1757W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs754531954, COSV99575081; called by muse, mutect2, varscan2
- THSD7A | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as rs778209809, COSV101439751; called by muse, mutect2, varscan2
- THSD7B | c.2857C>G p.Q953E | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV99751656; called by muse, mutect2, varscan2
- THSD7B | c.3470T>A p.L1157Q (on ENST00000272643; = p.L1155Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV99751660; called by muse, mutect2, varscan2
- TIMMDC1 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV99809607; called by muse, mutect2, varscan2
- TJP2 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs773962012, COSV55264663; called by muse, mutect2, varscan2
- TMEM108 | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV100418957, COSV58865927; called by muse, mutect2, varscan2
- TMEM150A | c.520G>A p.V174M (on ENST00000334462 / NM_001031738.3; = p.V121M on NM_153342.3) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100110538; called by muse, mutect2, varscan2
- TMEM178A | c.477A>C p.L159F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56142564, COSV99931903; called by muse, mutect2, varscan2
- TNIP3 | c.946+1G>C p.X316_splice | Splice Site (SNP) | VAF 34/55 reads (62%) | catalogued as COSV99284509; called by muse, mutect2, varscan2
- TNXB | c.6521T>C p.I2174T (on ENST00000647633; = p.I1927T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs751320202, COSV100926374; called by muse, mutect2, varscan2
- TNXB | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041163540, COSV100926375; called by muse, mutect2, varscan2
- TOP2A | c.3593G>A p.G1198E | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs925284735, COSV101396215; called by muse, mutect2, varscan2
- TOX2 | c.1045G>T p.G349W (on ENST00000358131 / NM_001098798.2; = p.G325W on NM_032883.3) | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV100363918; called by muse, mutect2, varscan2
- TRIM26 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101359473; called by muse, varscan2
- TRIM26 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101359475; called by muse, varscan2
- TRIM3 | c.1832G>C p.R611P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100624417, COSV61983200; called by muse, mutect2, varscan2
- TRIM38 | c.596G>T p.W199L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100837584; called by muse, mutect2, varscan2
- TRIM38 | c.597G>T p.W199C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100837585; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1693A>G p.K565E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.497); catalogued as COSV100709041; called by muse, mutect2, varscan2
- TSHZ3 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99551731; called by muse, mutect2, varscan2
- UFL1 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as COSV100990065, COSV100990076; called by muse, mutect2, varscan2
- UGT1A3 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 192/268 reads (72%) | SIFT tolerated (0.91); PolyPhen benign (0.074); catalogued as COSV100530303; called by muse, mutect2, varscan2
- UGT1A5 | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530302; called by muse, mutect2, varscan2
- UGT2B28 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV100158818; called by muse, mutect2, varscan2
- UGT8 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs568970139, COSV60420329; called by muse, mutect2, varscan2
- UPP2 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV99134929; called by muse, mutect2, varscan2
- USH2A | c.10847C>A p.S3616* | Nonsense Mutation (SNP) | VAF 60/87 reads (69%) | catalogued as COSV100235612; called by muse, mutect2, varscan2
- VIRMA | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV99888477; called by muse, mutect2, varscan2
- VIRMA | c.907A>T p.S303C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99888480; called by muse, mutect2, varscan2
- VNN3 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51592431, COSV99258327; called by muse, varscan2
- VPS13C | c.9625-1G>T p.X3209_splice (on ENST00000644861 / NM_020821.3; = p.X3166_splice on NM_017684.5) | Splice Site (SNP) | VAF 12/22 reads (55%) | catalogued as COSV99828593; called by muse, mutect2
- VPS13D | c.11609T>C p.L3870P | Missense Mutation (SNP) | VAF 54/85 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99166819; called by muse, mutect2, varscan2
- VPS50 | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 31/128 reads (24%) | catalogued as COSV100004846; called by muse, mutect2, varscan2
- VPS8 | c.718G>A p.A240T (on ENST00000625842 / NM_001349294.1; = p.A238T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99802285; called by muse, mutect2, varscan2
- VWF | c.2841G>T p.M947I | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV54638935; called by muse, mutect2, varscan2
- ZC3H14 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99193066; called by muse, mutect2, varscan2
- ZC3H7B | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV100687403; called by muse, mutect2, varscan2
- ZEB1 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100314478, COSV58051227; called by muse, mutect2, varscan2
- ZFHX3 | c.6251C>A p.P2084Q | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV51738103; called by muse, mutect2, varscan2
- ZFP82 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101089105; called by muse, mutect2, varscan2
- ZNF180 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99659892; called by muse, mutect2, varscan2
- ZNF317 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 44/71 reads (62%) | catalogued as COSV99927134; called by muse, mutect2, varscan2
- ZNF317 | c.766G>C p.G256R | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780575735, COSV56109446, COSV99927135; called by muse, mutect2, varscan2
- ZNF341 | c.1464C>G p.D488E (on ENST00000375200 / NM_001282935.1; = p.D481E on NM_032819.4) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as COSV100677868; called by muse, mutect2, varscan2
- ZNF385D | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs764335445, COSV99874836; called by muse, mutect2, varscan2
- ZNF530 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as COSV100252612; called by muse, mutect2, varscan2
- ZNF595 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100227711; called by muse, mutect2, varscan2
- ZNF671 | c.1484T>A p.I495N | Missense Mutation (SNP) | VAF 109/212 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV100235065; called by muse, mutect2, varscan2
- ZNF821 | c.167-2A>T p.X56_splice (on ENST00000425432 / NM_001376297.1; = p.X14_splice on NM_017530.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 75/138 reads (54%) | catalogued as COSV100546791; called by muse, mutect2, varscan2
- AXIN1 | c.794del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 80/147 reads (54%) | called by mutect2, pindel, varscan2
- C11orf87 | c.44del p.P15Rfs*27 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- COL12A1 | c.661dup p.D221Gfs*4 | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, mutect2
- DUOXA1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- DUXA | c.603del p.R202Efs*12 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- GRM1 | c.1116del p.W372Cfs*29 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- IGKV3D-7 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KEAP1 | c.1445_1447del p.N482_R483delinsS | In Frame Del (DEL) | VAF 30/56 reads (54%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.3026_3027insA p.A1010Gfs*12 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- MAPT | c.1237del p.R413Gfs*67 (on ENST00000262410 / NM_001377265.1; = p.R338Gfs*67 on NM_016835.4) | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | called by mutect2, pindel, varscan2
- MYH14 | c.1424del p.G475Afs*13 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- PDGFRB | c.316del p.R106Vfs*37 | Frame Shift Del (DEL) | VAF 59/175 reads (34%) | called by mutect2, pindel, varscan2
- PPM1L | c.639_643delinsA p.R214Gfs*22 | Frame Shift Del (DEL) | VAF 68/135 reads (50%) | called by pindel, varscan2*
- RBM26 | c.89_104del p.S30Lfs*6 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- ZNF43 | c.2135del p.G712Afs*84 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- ADAM10 | c.1299A>T p.S433= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99546142; called by muse, mutect2, varscan2
- ADAM9 | c.1101A>C p.A367= | Silent (SNP) | VAF 30/314 reads (10%) | catalogued as COSV101166126; called by muse, mutect2
- ADAMTS16 | c.3636C>T p.G1212= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99941373; called by muse, mutect2
- AKAP9 | c.3556C>T p.L1186= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1317561631, COSV100662439, COSV62344804; called by muse, mutect2, varscan2
- ARR3 | c.498G>A p.R166= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99333688; called by muse, mutect2, varscan2
- AVPR1A | c.915G>T p.A305= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV100146854; called by muse, mutect2, varscan2
- BIRC6 | c.10701C>T p.T3567= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV101428334; called by muse, mutect2, varscan2
- BRINP2 | c.222C>T p.F74= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as COSV64180707; called by muse, mutect2, varscan2
- BRINP3 | c.1869G>A p.E623= | Silent (SNP) | VAF 207/361 reads (57%) | catalogued as COSV66532347; called by muse, mutect2, varscan2
- C3AR1 | c.1044C>G p.P348= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as COSV99368585; called by muse, mutect2, varscan2
- CACNG7 | c.297G>T p.T99= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs967080427, COSV99712059; called by muse, mutect2, varscan2
- CADM1 | c.558A>T p.L186= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100522775; called by muse, mutect2, varscan2
- CBY2 | c.1263C>T p.T421= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs746466287, COSV100137530; called by muse, varscan2
- CDH10 | c.2061G>T p.R687= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV52571026, COSV52573259; called by muse, mutect2, varscan2
- CDO1 | c.27A>G p.P9= | Silent (SNP) | VAF 70/137 reads (51%) | catalogued as COSV99164789; called by muse, mutect2, varscan2
- CER1 | c.540T>A p.V180= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as COSV101097823; called by muse, mutect2, varscan2
- CFAP36 | c.48C>T p.I16= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV59117536, COSV59117710; called by muse, mutect2, varscan2
- CHRNE | c.690C>G p.V230= | Silent (SNP) | VAF 56/96 reads (58%) | catalogued as COSV99544977; called by muse, mutect2, varscan2
- CHST1 | c.1059G>T p.S353= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100346248; called by muse, mutect2, varscan2
- CTSG | c.360G>T p.R120= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV99361549; called by muse, mutect2, varscan2
- CTTNBP2 | c.126G>A p.R42= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs767966354, COSV99354019; called by muse, mutect2, varscan2
- CYP11B1 | c.636T>C p.V212= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99455162; called by muse, mutect2, varscan2
- DAAM1 | c.474A>T p.L158= | Silent (SNP) | VAF 62/107 reads (58%) | catalogued as COSV100658432; called by muse, mutect2, varscan2
- DEAF1 | c.714C>A p.T238= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100101619; called by muse, varscan2
- DEFB114 | c.90C>G p.T30= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100435399; called by muse, mutect2, varscan2
- DMWD | c.1551A>G p.P517= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV99353200; called by muse, mutect2, varscan2
- DNAJC10 | c.1152G>A p.L384= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV51135638, COSV51137242; called by muse, mutect2, varscan2
- ELOVL4 | c.711T>A p.L237= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100876279; called by muse, mutect2, varscan2
- ENPP6 | c.1308C>T p.L436= | Silent (SNP) | VAF 45/77 reads (58%) | catalogued as rs753760698, COSV57071513, COSV99698821; called by muse, mutect2, varscan2
- EPS8L1 | c.12C>A p.A4= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99136373; called by muse, mutect2, varscan2
- ETNK2 | c.864T>C p.F288= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV100916582; called by muse, mutect2, varscan2
- EXOC4 | c.1296G>A p.K432= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV99554099; called by muse, mutect2, varscan2
- FAAP100 | c.858G>A p.G286= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs1475166328, COSV100585389; called by muse, mutect2, varscan2
- FANCC | c.114G>T p.V38= | Silent (SNP) | VAF 58/119 reads (49%) | catalogued as COSV100002516; called by muse, mutect2, varscan2
- FIG4 | c.2406T>C p.Y802= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs765557108, COSV100019716; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMN2 | c.4830G>A p.K1610= | Silent (SNP) | VAF 33/42 reads (79%) | catalogued as COSV100145338; called by muse, mutect2, varscan2
- FOXI1 | c.432C>T p.L144= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100089368; called by muse, mutect2, varscan2
- FTSJ3 | c.1605T>C p.F535= | Silent (SNP) | VAF 45/304 reads (15%) | catalogued as COSV100834936; called by muse, mutect2, varscan2
- FURIN | c.432G>T p.G144= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV99184690; called by muse, mutect2, varscan2
- GABRG1 | c.804A>G p.R268= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV99778112; called by muse, mutect2, varscan2
- H1-10 | c.471G>T p.A157= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs776530231, COSV100412947; called by muse, varscan2
- H3C11 | c.138C>G p.T46= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs770440163, COSV100137907; called by muse, mutect2, varscan2
- H4C12 | c.309T>A p.G103= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100694789; called by muse, mutect2
- HCFC1 | c.2289C>T p.P763= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs200081632, COSV100129107; ClinVar: likely benign; called by muse, mutect2, varscan2
- HRNR | c.6988C>A p.R2330= | Silent (SNP) | VAF 83/890 reads (9%) | called by mutect2, varscan2
- HRNR | c.2631T>C p.A877= | Silent (SNP) | VAF 128/162 reads (79%) | catalogued as COSV100913514, COSV64257163; called by muse, mutect2, varscan2
- IL31RA | c.840G>T p.R280= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV99763198; called by muse, mutect2, varscan2
- KCNK16 | c.921G>A p.L307= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100949208, COSV100949213; called by muse, mutect2
- KCNU1 | c.2184G>A p.P728= | Silent (SNP) | VAF 45/492 reads (9%) | catalogued as rs368283762, COSV67754132, COSV67755719, COSV67757523; called by muse, mutect2
- KCTD7 | c.114G>A p.A38= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- KEL | c.751C>T p.L251= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100787096; called by muse, mutect2, varscan2
- KIF1A | c.945C>A p.L315= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV100241101; called by muse, mutect2, varscan2
- KIF21B | c.1071C>A p.T357= | Silent (SNP) | VAF 59/94 reads (63%) | catalogued as COSV100144595; called by muse, mutect2, varscan2
- KRR1 | c.703C>A p.R235= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV99875698, COSV99875835; called by muse, mutect2, varscan2
- LAMP2 | c.723G>A p.L241= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs1569369647, COSV99568502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LFNG | c.1038G>A p.V346= (on ENST00000222725 / NM_001040167.2; = p.V217= on NM_002304.2) | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99761809; called by muse, mutect2
- LILRA1 | c.996G>T p.P332= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs141507463, COSV99251930; called by muse, mutect2, varscan2
- LILRB3 | c.129C>T p.S43= | Silent (SNP) | VAF 21/182 reads (12%) | called by muse, mutect2, varscan2
- MARCHF9 | c.939C>T p.C313= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs768866705, COSV56984280; called by muse, mutect2
- MBNL1 | c.387A>T p.S129= | Silent (SNP) | VAF 97/464 reads (21%) | catalogued as COSV99220544; called by muse, mutect2, varscan2
- MOAP1 | c.906A>G p.A302= | Silent (SNP) | VAF 58/93 reads (62%) | catalogued as COSV99365713; called by muse, mutect2, varscan2
- MON2 | c.3186A>T p.S1062= | Silent (SNP) | VAF 77/167 reads (46%) | catalogued as COSV99742683; called by muse, mutect2, varscan2
- MT1B | c.165G>A p.E55= | Silent (SNP) | VAF 55/98 reads (56%) | catalogued as COSV100537453; called by muse, mutect2, varscan2
- NDUFA3 | c.147G>A p.T49= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as rs775161291, COSV52927689; called by muse, mutect2
- NLRP14 | c.1884G>A p.L628= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100205030; called by muse, mutect2, varscan2
- NMT2 | c.831G>C p.G277= | Silent (SNP) | VAF 49/123 reads (40%) | catalogued as COSV100975555; called by muse, mutect2, varscan2
- NRSN1 | c.403C>T p.L135= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV101027275; called by muse, mutect2, varscan2
- OR10J1 | c.816G>C p.L272= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV101419897, COSV101419991; called by muse, mutect2, varscan2
- OR11H1 | c.309C>A p.L103= | Silent (SNP) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- OR11H12 | c.30C>A p.G10= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV101612494; called by muse, mutect2, varscan2
- OR2C3 | c.243G>A p.Q81= | Silent (SNP) | VAF 50/72 reads (69%) | catalogued as COSV100825706; called by muse, mutect2
- OR2M2 | c.642C>A p.I214= | Silent (SNP) | VAF 305/409 reads (75%) | catalogued as COSV62897930, COSV62898755; called by muse, mutect2, varscan2
- OR4C13 | c.618G>T p.L206= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV101634188; called by muse, mutect2, varscan2
- OR4Q3 | c.615G>A p.E205= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV100057073; called by muse, mutect2, varscan2
- OR5H1 | c.891C>T p.V297= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100641709, COSV63402746; called by muse, mutect2, varscan2
- OR5I1 | c.153C>T p.I51= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV100041446; called by muse, mutect2, varscan2
- OR5L1 | c.711C>T p.A237= | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as rs1249263359, COSV100450061; called by muse, mutect2, varscan2
- PARD6G | c.90A>T p.R30= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- PCDHA11 | c.1542C>A p.G514= | Silent (SNP) | VAF 46/175 reads (26%) | catalogued as COSV100250830; called by muse, mutect2, varscan2
- PCDHB10 | c.2178C>A p.R726= | Silent (SNP) | VAF 62/216 reads (29%) | catalogued as COSV99504381; called by muse, mutect2, varscan2
- PCDHGB3 | c.1104G>T p.L368= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99539017; called by muse, mutect2, varscan2
- PHGDH | c.684G>A p.G228= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs745471026, COSV101025119; called by muse, mutect2, varscan2
- PKHD1L1 | c.8073T>C p.P2691= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV101006177; called by muse, mutect2, varscan2
- PLCD1 | c.1230C>T p.G410= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV99378883; called by muse, mutect2, varscan2
- PLCH1 | c.1362A>C p.A454= (on ENST00000340059 / NM_001130960.2; = p.A466= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/424 reads (10%) | catalogued as rs1236746017, COSV100396976; called by muse, mutect2
- PLXNC1 | c.813C>T p.T271= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99313202; called by muse, mutect2
- PPM1L | c.600A>G p.L200= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV99861810; called by muse, varscan2
- PPP1R9A | c.1218G>A p.V406= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99195765; called by muse, mutect2, varscan2
- PPP6R3 | c.1194G>T p.L398= (on ENST00000393800 / NM_001352375.2; = p.L347= on NM_018312.5) | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV55725495, COSV99676525; called by muse, mutect2, varscan2
- PRR23B | c.414G>A p.E138= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100272088; called by muse, mutect2
- PRSS23 | c.828A>G p.R276= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs113590440, COSV99722431; called by muse, mutect2, varscan2
- PRX | c.1713G>A p.E571= | Silent (SNP) | VAF 43/271 reads (16%) | catalogued as COSV99397744; called by muse, mutect2, varscan2
- PSKH1 | c.591G>T p.R197= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV52124222, COSV99344675; called by muse, mutect2, varscan2
- PTER | c.426G>C p.V142= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1401258053, COSV100126678; called by muse, mutect2, varscan2
- RB1CC1 | c.3000A>T p.I1000= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as COSV50265067, COSV99212277; called by muse, mutect2, varscan2
- SH2D3A | c.99C>T p.G33= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1381962109, COSV99838011; called by muse, mutect2, varscan2
- SH3PXD2B | c.913C>A p.R305= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100288059; called by muse, varscan2
- SLC22A9 | c.1167C>T p.V389= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV54171742; called by muse, mutect2, varscan2
- SLC45A2 | c.996G>C p.L332= | Silent (SNP) | VAF 31/37 reads (84%) | catalogued as COSV99672765; called by muse, mutect2, varscan2
- SLC66A1 | c.39C>T p.S13= | Silent (SNP) | VAF 94/175 reads (54%) | catalogued as COSV100913254; called by muse, mutect2, varscan2
- SMARCA4 | c.2424C>T p.I808= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as rs1060504452, COSV100758573; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPHKAP | c.3999T>C p.T1333= | Silent (SNP) | VAF 51/70 reads (73%) | catalogued as COSV100764138; called by muse, mutect2, varscan2
- STRN | c.2103G>T p.S701= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV55747063, COSV99815332; called by muse, mutect2, varscan2
- STXBP5L | c.3156A>G p.T1052= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs1303706395, COSV99874407; called by muse, mutect2, varscan2
- TBX20 | c.555G>A p.V185= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1424241927, COSV101282383; called by muse, mutect2, varscan2
- TCOF1 | c.813G>A p.E271= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100077528; called by muse, mutect2, varscan2
- TDRKH | c.264G>T p.V88= | Silent (SNP) | VAF 106/149 reads (71%) | catalogued as COSV100917963; called by muse, mutect2, varscan2
- TGFBR3 | c.1791A>G p.L597= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99283083; called by muse, mutect2, varscan2
- TLX3 | c.168C>T p.Y56= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99740642; called by muse, mutect2, varscan2
- TMEM74 | c.57G>A p.R19= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99865693; called by muse, mutect2, varscan2
- TRAV1-1 | c.171C>T p.G57= | Silent (SNP) | VAF 28/234 reads (12%) | catalogued as rs35116810; called by muse, mutect2
- TREM1 | c.684G>A p.T228= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs915151385, COSV55147803; called by muse, mutect2, varscan2
- TRPC4AP | c.1587G>T p.S529= | Silent (SNP) | VAF 101/150 reads (67%) | catalogued as COSV99328421; called by muse, mutect2, varscan2
- TSHZ3 | c.2667G>A p.Q889= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV53680978; called by muse, mutect2, varscan2
- VPS13D | c.10755G>A p.R3585= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs779699599, COSV99166814; called by muse, mutect2, varscan2
- XIRP2 | c.8019A>T p.S2673= (on ENST00000628543; = p.S2848= on NM_152381.6) | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as rs1267864114, COSV99743303; called by muse, mutect2, varscan2
- XKR4 | c.1095G>A p.K365= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV100532625, COSV100532714; called by muse, mutect2, varscan2
- ZBED9 | c.246C>T p.N82= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV101509260; called by muse, mutect2, varscan2
- ZNF215 | c.732A>G p.G244= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV99549643; called by muse, mutect2, varscan2
- AGAP7P | n.1792T>A | RNA (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- CD200R1 | c.68-16741C>T | Intron (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99867050; called by muse, mutect2, varscan2
- DCHS2 | n.3682A>G | RNA (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100601819; called by muse, mutect2, varscan2
- KNOP1P1 | n.130G>A | RNA (SNP) | VAF 69/102 reads (68%) | catalogued as rs1396061843; called by muse, mutect2, varscan2
- MIR522 | n.12G>T | RNA (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- SIAH1 | chr16:48365442 G>C | 5'Flank (SNP) | VAF 20/24 reads (83%) | catalogued as COSV100764616; called by muse, mutect2, varscan2
- TTN | c.10360+1953C>A | Intron (SNP) | VAF 46/91 reads (51%) | catalogued as COSV60323309; called by muse, mutect2, varscan2
- XIRP2 | c.*647G>T | 3'UTR (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99743306; called by muse, mutect2, varscan2
